CGCI case HTMCP-03-06-02194 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e291f138-8517-4add-b647-d96647835168

Demographics
Sex at birth: female; Race: black or african american; Age at index: 46 years; Vital status: Dead; Days to death: 605 days (1.7 years).

Diagnoses (1)
1. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T2b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 605 days (1.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 56 days; Days to treatment end: 78 days; Treatment dose: 45.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 367 days (1.0 years); Days to treatment end: 367 days (1.0 years); Treatment dose: 10.
   Treatment given: Treatment type: Brachytherapy, Low Dose; Treatment intent type: Adjuvant; Treatment dose: 3000; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 1000; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4500; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 3 days; Disease response: With Tumor.
- Days to follow up: 410 days (1.1 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 605.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Weight: 47 kg; Height: 154.8 cm; BMI: 19.6; Hormonal contraceptive use: Never Used; Menopause status: Perimenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02194-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02194-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Days from index date to last known alive: 3; Tumor status: With tumor; Live birth pregnancy count: 7; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 7; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Basaloid Squamous Cell; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Follow-up form 1, Treatment, Radiation therapy info: Brachytherapy type: LDR; Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Treatments, Treatment 1: Therapy regimen: Progression; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 10.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02194-01A-01R-6194:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02194-01A-01D-6194:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02194-10A-01D-6194:
- % tumour top: 0
- % tumour bottom: 0
